Somatic mutation profile of tumor specimen MP2PRT-PASVME-TMP1-A (aliquot MP2PRT-PASVME-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASVME, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.9 years (2,897 days).
Specimen MP2PRT-PASVME-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c305ad92-3b5a-482f-b0d4-5a508ed0c78c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASVME-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASVME-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db6abaed-03d1-4f96-8a27-6db3f5228fd2

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG5 | c.990G>T p.K330N | Missense Mutation (SNP) | VAF 113/302 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as rs1339151172, COSV99575211; called by muse, mutect2, varscan2
- CAMK4 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 127/323 reads (39%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); catalogued as rs972309056; called by muse, mutect2, varscan2
- CHTF18 | c.2232C>G p.I744M | Missense Mutation (SNP) | VAF 216/567 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.081); catalogued as COSV50210153, COSV50210621, COSV50210771; called by muse, mutect2, varscan2
- DSG3 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 22/301 reads (7%) | catalogued as COSV57126970; called by muse, mutect2
- ELL | c.907G>A p.G303R | Missense Mutation (SNP) | VAF 144/396 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); catalogued as rs1244309794; called by muse, mutect2, varscan2
- HEPH | c.361C>T p.R121C (on ENST00000343002; = p.R175C on NM_138737.5) | Missense Mutation (SNP) | VAF 11/192 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1202646859, COSV57965409; called by muse, mutect2
- MUC2 | c.2902G>A p.V968I | Missense Mutation (SNP) | VAF 14/374 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs572797801; called by muse, mutect2
- CKMT1A | c.1078A>C p.T360P | Missense Mutation (SNP) | VAF 13/424 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- DEPDC1B | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 80/206 reads (39%) | called by muse, mutect2, varscan2
- H1-10 | c.340T>G p.F114V | Missense Mutation (SNP) | VAF 34/686 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- HGF | c.205C>A p.Q69K | Missense Mutation (SNP) | VAF 116/357 reads (32%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCNX1 | c.2204C>T p.S735F | Missense Mutation (SNP) | VAF 120/338 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PIEZO2 | c.3198C>G p.I1066M | Missense Mutation (SNP) | VAF 95/262 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PTPN13 | c.6082C>G p.Q2028E (on ENST00000411767 / NM_080683.3; = p.Q2009E on NM_006264.3) | Missense Mutation (SNP) | VAF 15/329 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- TXNRD3 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 24/382 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2
- URB1 | c.5053A>G p.I1685V | Missense Mutation (SNP) | VAF 50/518 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- EPHA10 | c.2865G>A p.A955= | Silent (SNP) | VAF 153/419 reads (37%) | catalogued as rs372596326; called by muse, mutect2, varscan2
- IGHV3-53 | chr14:106592669 del CACTGTGTC | Silent (DEL) | VAF 7/26 reads (27%) | called by mutect2, varscan2
- KLK14 | c.204C>T p.C68= | Silent (SNP) | VAF 110/305 reads (36%) | catalogued as rs369907925; called by muse, mutect2, varscan2
- ABI3BP | c.1577-8510C>T | Intron (SNP) | VAF 19/385 reads (5%) | catalogued as rs1213387037; called by muse, mutect2
